Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7078, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7078-01A (Primary Tumor).

[page 1 of 2]
TCGA-HC-7078

Collected:
Received:
Reported:

Accession:
Acct / Reg #:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A. Bilateral pelvic lymph node dissection:
Three benign hyperplastic lymph nodes.

B. Radical prostatectomy:
Tumor Characteristics:

1. Histologic type: Adenocarcinoma, conventional type.

2. Gleason Grade:

a. Primary pattern: 3/5.

b. Secondary pattern: 4/5.

C. Score: 7/10.

3. Tumor involves: Both lobes.

4. Tumor quantitation: Tumor involves approximately 20% of gland volume.

5. Seminal vesicle involvement: Not identified.

6. Extra-capsular tumor extension: Yes, focal in left posterior region.

7. Lympho-vascular space invasion: Not identified.

8. Perineural space invasion: Absent.

9. High grade PIN: Present.

Surgical Margin Status:

1. Bladder Neck: Negative.

2. Apical (Inferior): Negative.

3. Inked prostatic margin: Negative.

Lymph Node Status:

1. Total number of lymph nodes examined: 3.

2. Number of lymph nodes containing metastatic carcinoma: None.

Other significant findings:

1. Frozen section correlation statement: None.

2. Other findings: Benign prostatic hyperplasia.

3. pTNM stage: pT3aN0, MX.

[page 2 of 2]
CLINICAL HISTORY:

Preoperative Diagnosis: Malignant neoplasm of prostate.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Bilateral pelvic lymph nodes.

B. Prostate.

GROSS DESCRIPTION:

A. Received in a single container labeled [REDACTED], bilateral pelvic nodes are two pieces of yellow-brown fibroadipose tissue measuring in aggregate 5 x 3 x 1.5 cm. Sectioning reveals three probable lymph nodes measuring from 0.3 up to 2.2 cm. The lymph nodes are entirely submitted in cassettes [REDACTED] as follows: one probable node in block 1; one probable node bisected in blocks 2-3; one probable node sectioned in blocks 4-6.

B. Received in a single container labeled [REDACTED], prostate is a prostate gland with attached seminal vesicals. The prostate measures 5 x 6 x 3 cm. and weighing 51 grams. The attached seminal vesicals measure in average 2.5 cm. in length and 1 cm. in diameter and are grossly unremarkable. The seminal vesicals also measure 2.5 cm. in length and 0.2 cm. in average diameter and likewise are grossly unremarkable. The specimen has been received previously inked, the right half is inked yellow and the left half has been inked black. The cut surface of the prostate is yellow to gray-tan and multinodular. There is no definite mass lesion grossly identified. Received with the specimen are two cassettes, one green, one yellow and labeled [REDACTED]. Representative sections are submitted in cassette [REDACTED] as follows: right seminal vesical and vas block 1; left seminal vesical and vas block 2; sections taken from apical margin in block 3; base margin in block 4; prostate section from base to apex are submitted as follows: level I left posterior block 5; left anterior block 6; right anterior block 7; right posterior block 8; level II left posterior block 9; left anterior block 10; right anterior block 11; right posterior block 12; level III left posterior block 13; left anterior block 14; right anterior block 15; right posterior block 16.

Source: NCI Genomic Data Commons file cefb43aa-03c3-4df7-992a-9154aab61065 (TCGA-HC-7078.FB3865DF-5E90-4A2F-B684-063D41369BFC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).